Gene-level copy-number profile of tumor specimen ALCH-B2BA-TTP1-A from ALCHEMIST case ALCH-B2BA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.4 years (21,678 days).
Specimen ALCH-B2BA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a87ad86-4dc0-4178-a838-f9e7d6f5247e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2BA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/a5b0c7b6-8e97-4939-baa6-8c459007bf1b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 729; copy number 1: 4,616; copy number 2: 18,490; copy number 3: 16,174; copy number 4: 10,358; copy number 5: 4,139; copy number 6: 1,890; copy number 7: 1,224; copy number 8: 225; copy number 9: 274; copy number 10: 109; copy number 11: 137; copy number 12: 90; copy number 13: 177; copy number 14: 102; copy number 15: 72; copy number 16: 11; copy number 17: 60; copy number 18: 1; copy number 19: 5; copy number 21: 1; copy number 22: 4; copy number 33: 6; copy number 40: 5.

Homozygous deletions (total copy number 0; autosomes only): 217 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,673,141–113,073,113, 16 genes: MOV10, AL603832.1, RHOC, AL603832.3, PPM1J, AL603832.2, TAFA3, NUTF2P4, LINC01356, LINC01357, AL390729.1, SLC16A1, AKR7A2P1, SLC16A1-AS1, AL390242.1, LRIG2-DT.
- chr1:120,419,850–120,467,739, 2 genes: NBPF8, PFN1P2.
- chr2:131,492,813–131,521,573, 1 gene: SMPD4BP.
- chr2:186,364,598–186,695,287, 5 genes (within-gene range 0–3): MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1.
- chr3:67,654,669–67,947,713, 1 gene: SUCLG2-AS1.
- chr3:75,415,070–75,538,029, 5 genes: ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr4:49,523,648–49,524,185, 2 genes: AC119751.2, AC119751.8.
- chr5:59,703,606–60,033,020, 2 genes (within-gene range 0–2): MIR582, AC034234.1.
- chr6:85,731,371–85,869,464, 5 genes: AL355615.1, SMIM11P1, RNU4-72P, Y_RNA, AL450338.1.
- chr7:140,404,058–140,722,790, 10 genes (within-gene range 0–2): RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1.
- chr10:38,403,189–38,452,153, 1 gene (within-gene range 0–2): AL133216.2.
- chr10:38,452,987–38,455,365, 1 gene (within-gene range 0–4): CICP9.
- chr13:19,172,773–19,181,824, 2 genes: AL139327.3, TUBA3C.
- chr15:21,293,653–22,617,854, 70 genes (broad region; genes not listed).
- chr15:52,109,263–52,206,915, 6 genes (within-gene range 0–2): BCL2L10, GNB5, AC023906.3, AC023906.4, Y_RNA, CERNA1.
- chr16:12,560,756–12,611,044, 1 gene (within-gene range 0–1): AC010333.2.
- chr16:14,301,389–14,418,908, 5 genes: MIR193BHG, MIR193B, MIR365A, LINC02130, AC040173.1.
- chr19:9,083,112–9,083,398, 1 gene: OR1M4P.
- chr21:9,053,122–9,129,752, 4 genes: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:17,296,219–17,296,596, 1 gene: AP000457.1.
- chr22:17,592,136–19,172,839, 75 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,532 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:16,354,256–18,560,679, 19 genes, copy number 5 (within-gene range 4–5): AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1, KCNS3, AC079802.1, AC079148.1, RDH14.
- chr2:19,868,860–20,679,243, 29 genes, copy number 5: LINC00954, TTC32, AC013400.1, WDR35, AC079145.1, MATN3, LAPTM4A, LAPTM4A-DT, AC098828.1, RPS16P2, RN7SL140P, RNU6-961P, SDC1, DRG1P1, RNU7-113P, PUM2, SLC7A15P, RNA5SP86, RHOB, AC023137.1, Y_RNA, AC012065.1, NDUFAF2P1, HS1BP3, AC012065.2, HS1BP3-IT1, RPS25P3, GDF7, AC012065.3.
- chr3:11,745–409,417, 6 genes, copy number 5 (within-gene range 3–5): LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6.
- chr3:103,630,661–178,937,352, 1,180 genes, copy number 5–7 (broad region; genes not listed).
- chr3:181,372,732–198,123,232, 386 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–38,845,829, 581 genes, copy number 5–7 (broad region; genes not listed).
- chr5:42,892,319–45,895,970, 50 genes, copy number 5: PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:31,010,474–32,763,532, 163 genes, copy number 5 (broad region; genes not listed).
- chr6:43,295,694–44,450,425, 52 genes, copy number 5: SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642.
- chr6:45,097,496–47,832,780, 40 genes, copy number 5: AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P.
- chr6:50,514,035–54,390,142, 81 genes, copy number 5 (broad region; genes not listed).
- chr6:115,633,540–126,348,875, 121 genes, copy number 5–6 (broad region; genes not listed).
- chr6:127,118,671–170,738,536, 704 genes, copy number 5 (broad region; genes not listed).
- chr7:37,032–40,979,939, 706 genes, copy number 5–17 (broad region; genes not listed).
- chr7:46,261,064–55,732,431, 108 genes, copy number 5–33 (broad region; genes not listed).
- chr7:80,096,600–81,770,438, 19 genes, copy number 6: RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF.
- chr7:85,381,118–111,562,517, 500 genes, copy number 8–40 (broad region; genes not listed).
- chr8:39,867,436–40,402,010, 13 genes, copy number 5: AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1.
- chr8:55,696,424–102,124,907, 726 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:101,847,256–140,458,579, 436 genes, copy number 6 (broad region; genes not listed).
- chr8:140,657,900–145,066,685, 191 genes, copy number 5–7 (broad region; genes not listed).
- chr10:71,364,243–88,975,153, 352 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:103,877,374–105,534,765, 23 genes, copy number 5–6: AL133355.1, STN1, SLK, RN7SL524P, COL17A1, MIR936, SFR1, CFAP43, MIR609, GSTO1, MIR4482, GSTO2, ITPRIP, AL162742.1, AL162742.2, ITPRIP-AS1, CFAP58-DT, CFAP58, LINC02620, AL161646.1, SORCS3, SORCS3-AS1, RNU6-463P.
- chr11:31,369,840–46,177,106, 215 genes, copy number 5–13 (broad region; genes not listed).
- chr11:94,415,570–96,507,574, 44 genes, copy number 5 (within-gene range 4–5): MRE11, MIR548L, AP000786.1, ANKRD49, C11orf97, FUT4, PIWIL4, AP000943.2, AP000943.3, AP000943.1, LINC02700, AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82, JRKL.
- chr11:101,451,564–107,018,476, 90 genes, copy number 5 (broad region; genes not listed).
- chr12:24,223,233–25,648,579, 29 genes, copy number 7–8: SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.
- chr12:28,821,975–29,340,980, 7 genes, copy number 7–14 (within-gene range 2–14): AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1.
- chr14:21,841,240–22,552,156, 120 genes, copy number 6 (broad region; genes not listed).
- chr14:36,061,026–37,172,606, 24 genes, copy number 5 (within-gene range 2–5): AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1.
- chr14:67,360,328–106,879,812, 1,105 genes, copy number 6–12 (broad region; genes not listed).
- chr15:85,380,571–85,749,358, 10 genes, copy number 5 (within-gene range 3–5): AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3.
- chr18:24,685,772–28,177,946, 48 genes, copy number 5: RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, CDH2, AC110015.1, AC006249.1.
- chr19:55,338,945–55,407,788, 12 genes, copy number 6: AC020922.4, KMT5C, COX6B2, AC020922.1, FAM71E2, IL11, TMEM190, AC020922.3, TMEM238, RPL28, MIR6805, UBE2S.
- chr20:5,544,439–13,996,443, 105 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:38,926,312–40,126,357, 14 genes, copy number 5: FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, ATG3P1, RN7SL680P, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1.
- chr20:50,190,830–50,585,241, 10 genes, copy number 6 (within-gene range 4–6): CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1.
- chr20:52,192,159–55,684,915, 36 genes, copy number 5 (within-gene range 4–5): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.
- chr20:61,953,469–64,327,972, 136 genes, copy number 6 (broad region; genes not listed).
- chr22:46,039,907–46,069,891, 6 genes, copy number 6: LINC00899, PRR34, AL121672.3, PRR34-AS1, AL121672.1, AL121672.2.

Autosomal genes at a single copy (total copy number 1): 3,791. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
